Gene-level copy-number profile of tumor specimen TCGA-ZF-A9RC-01A from TCGA case TCGA-ZF-A9RC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.4 years (28,275 days).
Specimen TCGA-ZF-A9RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c728eb10-62f7-4021-810a-6cc2984a9a14.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9RC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef4ffa7f-31f5-4b9b-aed4-8ca6020827d5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,353; copy number 2: 5,488; copy number 3: 45,084; copy number 4: 5,623; copy number 5: 623; copy number 6: 114; copy number 7: 76; copy number 8: 147; copy number 9: 138; copy number 11: 108; copy number 13: 8; copy number 15: 11; copy number 16: 27; copy number 31: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9RC-01A-11D-A38F-01): tumor purity 0.2, ploidy 6.48, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 515 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,129,464–43,270,936, 156 genes, copy number 9–11 (within-gene range 3–11) (broad region; genes not listed).
- chr1:150,363,091–150,913,292, 27 genes, copy number 9 (within-gene range 5–9): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51.
- chr1:185,157,080–185,291,781, 1 gene, copy number 7 (within-gene range 6–7): SWT1.
- chr1:185,226,808–189,133,292, 52 genes, copy number 7: RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75.
- chr8:51,257,688–52,745,843, 19 genes, copy number 7: AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr8:55,102,028–56,588,787, 32 genes, copy number 8–13: XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6.
- chr8:99,796,615–102,561,018, 77 genes, copy number 8–11 (broad region; genes not listed).
- chr8:103,016,744–103,332,866, 14 genes, copy number 8 (within-gene range 3–8): NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2.
- chr12:68,487,687–72,670,758, 82 genes, copy number 8–31 (broad region; genes not listed).
- chr22:20,198,729–21,081,018, 55 genes, copy number 8: AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
